Gene-level copy-number profile of tumor specimen ALCH-B4XH-TTP1-A from ALCHEMIST case ALCH-B4XH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.1 years (22,307 days).
Specimen ALCH-B4XH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 16583f83-7fa7-4476-89ea-2a4eb5c0e37a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4XH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/82f697ab-7909-4284-80f4-f0060cdbc934

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 6,413; copy number 2: 51,287; copy number 3: 978; copy number 4: 131; copy number 5: 78; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:187,270,698–187,270,804, 1 gene (within-gene range 0–2): RNU6-989P.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr3:184,186,023–184,194,012, 1 gene (within-gene range 0–2): ABCF3.
- chr5:177,438,503–177,503,647, 6 genes (within-gene range 0–2): PRR7-AS1, PRR7, DBN1, AC145098.2, PDLIM7, AC145098.1.
- chr8:43,511,820–43,674,591, 7 genes: AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr9:132,582,606–132,590,252, 1 gene: BARHL1.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr17:29,569,580–29,570,519, 1 gene (within-gene range 0–2): AC104564.3.
- chr22:24,248,074–24,265,525, 3 genes: GGTLC4P, POM121L9P, BCRP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 79 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:62,463,497–63,740,398, 77 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:43,414,483–43,453,902, 2 genes, copy number 5–13: SIK1, LINC00319.

Autosomal genes at a single copy (total copy number 1): 3,719. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
